Somatic mutation profile of tumor specimen BA2772D (aliquot aq-BA2772D) from BEATAML1.0 case 2397, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 61.3 years (22,404 days).
Specimen BA2772D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90db8016-08e3-4c9f-bd24-1769b586ca9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2321D (Solid Tissue Normal), aliquot aq-BA2321D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/89f19abb-6f7f-433b-b52c-f170343299b2

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, 3'UTR 1, Frame Shift Ins 1, 5'UTR 1, Nonsense Mutation 1, Splice Region 1, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NPM1 | c.860_863dup p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 33/104 reads (32%) | catalogued as rs587776806, COSV51548899, COSV51555098, COSV51559390, COSV51564309; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PYGB | c.578C>A p.A193E | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.04); catalogued as COSV53818172; called by muse, mutect2, varscan2
- DPP6 | c.1233C>A p.C411* (on ENST00000377770 / NM_001364500.2; = p.C349* on NM_001936.5) | Nonsense Mutation (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- HSPA4 | c.1118C>G p.T373S | Missense Mutation (SNP) | VAF 78/157 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- PITX3 | c.324G>T p.V108= | Splice Region (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- PNPLA5 | c.596G>A p.S199N | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, varscan2
- THBS2 | c.867G>T p.Q289H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.195); called by muse, mutect2
- GSE1 | c.3630C>A p.G1210= | Silent (SNP) | VAF 3/52 reads (6%) | called by muse, mutect2
- ARID2 | chr12:45727495 T>C | 5'Flank (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- CRCP | c.-114C>A | 5'UTR (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- EOMES | c.*2G>T | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
